Gene-level copy-number profile of tumor specimen TCGA-D9-A6EA-06A from TCGA case TCGA-D9-A6EA, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 71.2 years (26,004 days).
Specimen TCGA-D9-A6EA-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.cf8456d1-9563-4352-8d4f-52bb806276aa.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D9-A6EA-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1233157e-a455-44fd-93ea-6270e33bdb8b

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 488; copy number 2: 5,885; copy number 3: 12,475; copy number 4: 14,114; copy number 5: 10,624; copy number 6: 7,071; copy number 7: 4,471; copy number 8: 2,192; copy number 9: 24; copy number 10: 142; copy number 11: 452; copy number 12: 1,351; copy number 13: 68; copy number 14: 142; copy number 15: 78; copy number 16: 112; copy number 17: 23; copy number 18: 102.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D9-A6EA-06A-11D-A30W-01): tumor purity 0.85, ploidy 4.57, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,494 genes in 32 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:4,436,850–5,694,742, 23 genes, copy number 9: AC106799.3, AC106799.2, AC106799.1, AC010634.1, LINC02114, AC026719.1, AC026415.1, AC010451.3, AC010451.1, LINC01020, AC010451.2, LINC02121, RN7SKP73, CTD-2297D10.2, ADAMTS16, AC022424.1, ALG3P1, AC091978.1, MTCO1P30, MTCO2P30, MTCO1P31, ICE1, AC026736.1.
- chr5:65,665,928–66,093,937, 8 genes, copy number 12: SGTB, NLN, AC008958.1, AC010359.2, ERBIN, AC010359.1, AC010359.3, AC025442.2.
- chr5:80,408,013–80,960,907, 15 genes, copy number 11: ZFYVE16, AC008771.1, FAM151B, RPS27AP9, RPL7P24, ANKRD34B, DBIP2, LINC01337, DHFR, AC008434.1, MTRNR2L2, MSH3, AC022493.2, AC022493.1, RASGRF2-AS1.
- chr5:80,997,183–80,998,047, 1 gene, copy number 11: AC026427.2.
- chr5:83,637,805–90,410,669, 76 genes, copy number 14 (broad region; genes not listed).
- chr5:92,410,256–92,844,992, 4 genes, copy number 11 (within-gene range 7–11): AC124854.1, AC026780.1, AC026780.2, AC008517.1.
- chr5:96,741,079–97,057,358, 10 genes, copy number 11: AC020900.1, ERAP1, AC008906.1, AC008906.2, AC009126.1, ERAP2, LNPEP, AC008850.1, Y_RNA, SETP22.
- chr5:97,091,867–97,216,074, 5 genes, copy number 11 (within-gene range 8–11): LIX1, RIOK2, RNU1-73P, AC008883.3, AC008883.1.
- chr5:99,594,329–107,670,937, 66 genes, copy number 10–15 (within-gene range 7–15) (broad region; genes not listed).
- chr5:112,419,583–114,496,500, 21 genes, copy number 12 (within-gene range 1–12): EPB41L4A-DT, HMGB3P16, AC137549.1, LINC02200, APC, CBX3P3, RNU6-482P, AC008575.1, SRP19, REEP5, XBP1P1, ZRSR2P1, DCP2, MCC, AC079465.1, TSSK1B, RNU4ATAC13P, YTHDC2, AC093240.1, KCNN2, RN7SKP89.
- chr5:136,303,757–154,038,936, 440 genes, copy number 12 (broad region; genes not listed).
- chr5:163,039,291–170,736,632, 77 genes, copy number 11 (within-gene range 5–11) (broad region; genes not listed).
- chr8:66,562,175–67,407,072, 21 genes, copy number 11: MYBL1, VCPIP1, Y_RNA, C8orf44-SGK3, C8orf44, SGK3, PTTG3P, MCMDC2, SNHG6, SNORD87, TCF24, PPP1R42, AC110998.1, COPS5, CSPP1, RNA5SP268, AC087359.1, ARFGEF1, AC021321.2, AC021321.1, AC011037.1.
- chr8:78,516,340–145,066,685, 1,059 genes, copy number 10–12 (broad region; genes not listed).
- chr10:1,957,589–3,991,259, 37 genes, copy number 12–17: AL355597.1, LINC00700, AL441943.1, MIR6072, RNU6-889P, AL441943.2, LINC02662, RNU6-576P, LINC00701, LINC02645, AL713851.2, AL713851.1, AL355361.1, AC026396.1, AL731533.1, AL731533.3, AL731533.2, PFKP, AL451164.2, PITRM1, PITRM1-AS1, AL451164.3, AL451164.1, LINC02668, AL139280.1, AL139280.3, AL139280.2, AL356433.1, LINC02669, AL357833.1, AL450322.2, AL450322.1, KLF6, AL513303.1, LINC02639, LINC02660, MIR6078.
- chr10:5,122,087–5,566,881, 19 genes, copy number 12: AKR1C5P, AKR1C8P, AKR1C4, ARL4AP3, AL355303.2, AL355303.1, LINC02561, AKR1C7P, RPL26P28, AL683826.1, UCN3, TUBAL3, NET1, CALML5, CALML3-AS1, CALML3, AL732437.1, AL732437.3, AL732437.2.
- chr10:8,724,010–8,973,468, 3 genes, copy number 12: AL355333.1, LINC02676, AC044784.1.
- chr13:34,545,929–34,696,612, 1 gene, copy number 10 (within-gene range 4–10): AL161716.1.
- chr13:50,994,511–52,700,909, 53 genes, copy number 13: GUCY1B2, RNA5SP29, C13orf42, RPL5P31, AL157817.1, PRELID3BP2, FAM124A, SERPINE3, MIR5693, INTS6, INTS6-AS1, RPS4XP16, RN7SL320P, SNRPGP11, MIR4703, RNU6-65P, WDFY2, RNY1P6, RN7SL413P, ATP5PBP1, AL162377.3, DHRS12, AL162377.1, TMEM272, CCDC70, CTAGE3P, AL162377.2, ATP7B, FABP5P2, ALG11, UTP14C, NEK5, AL139082.1, NEK3, MRPS31P5, AL158066.1, THSD1P1, AL158066.2, TPTE2P2, LINC02333, THSD1, RNY4P24, VPS36, AL359513.1, CKAP2, LINC00345, AL137058.1, AL137058.3, AL137058.2, MRPS31P4, HNRNPA1L2, SUGT1-DT, SUGT1.
- chr13:53,207,831–53,801,489, 1 gene, copy number 18 (within-gene range 2–18): AL356295.1.
- chr13:54,115,783–54,142,319, 1 gene, copy number 9 (within-gene range 2–9): LINC00458.
- chr13:54,938,604–55,174,548, 4 genes, copy number 18: AL390964.1, LINC02335, AL139038.1, MIR5007.
- chr13:85,046,001–87,458,407, 18 genes, copy number 10–12: AL356313.1, LINC00375, AL160154.1, LINC00351, AL356413.1, SLITRK6, AL162373.1, MOB1AP1, AL354994.1, FO624990.1, DDX6P2, AL445207.1, TXNL1P1, LINC00430, UBBP5, LIN28AP2, AL360267.2, AL360267.1.
- chr13:89,402,398–90,231,682, 11 genes, copy number 13 (within-gene range 5–13): LINC02336, LINC01040, LINC00353, RPL7L1P1, AL355821.1, PEX12P1, LINC00559, RNA5SP34, FAR1P1, KRT18P27, MIR622.
- chr13:92,446,470–94,408,020, 14 genes, copy number 15 (within-gene range 8–15): AL159152.1, GPC5-IT1, MIR548AS, AL356737.2, AL356737.1, GPC5-AS1, LINC00363, AL354811.2, AL354811.1, GPC6, AL160159.1, HNRNPA1P29, GPC6-AS2, RNA5SP35.
- chr13:99,200,774–99,386,504, 1 gene, copy number 10 (within-gene range 2–10): UBAC2.
- chr13:99,254,714–101,720,856, 43 genes, copy number 10: GPR18, GPR183, MIR623, HMGB3P4, CCR12P, AL136961.1, TM9SF2, LINC01232, AL139035.1, LINC00449, LINC01039, CFL1P8, AL139035.2, CLYBL, MIR4306, CLYBL-AS2, CLYBL-AS1, AL137139.1, AL137139.3, AL137139.2, ZIC5, AL355338.1, ZIC2, LINC00554, NDUFA12P1, PCCA-DT, ASNSP3, PCCA, RPL15P18, AL356575.1, AL353697.1, PCCA-AS1, GGACT, AL356966.1, AL136526.1, RPS26P47, TMTC4, COX5BP6, NALCN-AS1, ARF4P3, LINC00411, NALCN, ITGBL1.
- chr13:101,717,564–101,723,106, 1 gene, copy number 10: AL160153.1.
- chr13:107,163,510–107,867,496, 4 genes, copy number 13 (within-gene range 5–13): FAM155A, SNORD31B, AL445649.1, MIR1267.
- chr20:87,250–1,940,592, 61 genes, copy number 10 (broad region; genes not listed).
- chr20:2,864,184–9,839,076, 130 genes, copy number 11–18 (within-gene range 7–18) (broad region; genes not listed).
- chr20:13,368,291–26,251,546, 266 genes, copy number 14–18 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 488. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
